Surgical pathology report (de-identified scan), TCGA case TCGA-BL-A5ZZ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-BL-A5ZZ-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, urothelial 8/20/13
Site Bladder, posterior wall
C67.4
Jed 4/12/13

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Ureteral margin, right, excision:
Negative for tumor.

B.. Ureteral margin, left, excision:
Negative for tumor.

C. Bladder, excision:
Invasive high grade urothelial carcinoma (see tumor characteristics in the microscopic description).

D. Lymph nodes, left pelvic, excision:
Two lymph nodes negative for metastatic carcinoma (0/2).

E. Lymph nodes, right pelvic, excision:
Two lymph nodes negative for metastatic carcinoma (0/2).

Microscopic Description:

Histologic type: Urothelial carcinoma

Histologic grade: High grade

Tumor size: 4 cm

Primary tumor (pT): Tumor invades into the vaginal wall, pT4a.

Margins of resection: The distal urethral margin shows high-grade papillary urothelial carcinoma with no invasion. The ureteral margins are negative. The outer soft tissue margins of the specimen are negative.

Vascular invasion: Present

Regional lymph nodes (pN): pN0

Distant metastasis (pM): pMX

Other findings: Other areas of urothelial atypia with severe atypia and focal papillary urothelial carcinoma are present.

The tumor shows extensive necrosis. Immunohistochemical stains with the neural markers synaptophysin, chromogranin and CD 56 are performed.

The synaptophysin and chromogranin are negative. CD 56 is focally positive suggestive of focal neuroendocrine differentiation within the tumor.

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

Specimen

- A. Right ureteral margin
- B. Left ureteral margin
- C. Bladder
- D. Left pelvic node
- E. Right pelvic node

Clinical Information

Bladder cancer

[page 2 of 2]
Intraoperative Consultation

- A) Ureteral margin, right, excision: Negative for tumor.
- B) Ureteral margin, left, excision: Negative for tumor.

Gross Description

A. Received fresh labeled "right ureteral margin" is a stapled tissue specimen that measures 1.2 cm in diameter and 0.3 cm in wall thickness. The tissue is cut away from the staple and entirely frozen. AFS1

B. Received fresh labeled "left ureteral margin" is doughnut shaped specimen that measures 0.3 x 0.3 x 0.2 cm in dimension. Entirely frozen.

C. Received fresh labeled "bladder" is a 6.5 x 6.5 x 4.8 cm symmetrical bladder with attached 2.5 cm urethra, a copious amount of pericystic adipose tissue and bilateral ureters averaging 2.5 cm in length. The ureters and urethra are probe patent to the bladder lumen. A 4.5 x 3.5 cm portion of wrinkled tan-pink vaginal mucosa is present along the posterior aspect. The right half of the specimen is inked blue and the left half is inked black. On opening, there is a 4.0 x 3.8 cm papilliferous, twisting tan-white to chalky yellow-white tumor mass occupying the right lateral posterior wall. The tumor surrounds the ureteral orifice. On sectioning, the tumor has a maximal thickness of 2.5 cm, grossly extending to within 0.4 cm of the inked surface of the specimen. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. The tumor involving the posterior wall extends to within uro-0.2 cm of the vaginal mucosa. The remaining bladder mucosa is glistening tan-pink to tan-red with normal folds and the wall averages 0.9 cm in thickness. An area of tan-red edematous mucosa is noted just superior to the tumor along the posterior wall. No additional mass lesion or abnormality is noted.

Summary: 1 - urethral margin en face, 2 - right ureteral orifice, 3 - left ureteral orifice, 4 and 5 - right lateral wall, 6 through 8 - tumor to posterior vaginal mucosa, 9 - bladder to urethra, 10 - left lateral wall including area of edema, 11 - Dome/posterior wall, 12 - anterior wall

D. Received fresh labeled "left pelvic node" is a 5.5 x 4.3 x 2.0 cm portion of soft, lobulated tan gold adipose tissue. Two rubbery tan-pink-gold tissues in keeping with lymph nodes measuring up to 5.4 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted.

Summary: 1 - 1 bisected lymph node, 2 through 4 - largest lymph node

E. Received fresh labeled "right pelvic node" is a 4.9 x 3.4 x 1.0 cm portion of soft, lobulated tan gold adipose tissue. Two slightly rubbery tan-pink-gold tissues in keeping with lymph nodes measuring up to 3.5 cm are recovered.

Summary: 1 - 1 bisected lymph node, 2 and 3 - bisected larger lymph node

Source: NCI Genomic Data Commons file 5b445b19-7b46-4a88-b754-e49cb6aabe6b (TCGA-BL-A5ZZ.DDA3DBFA-0ECA-4D47-8E8D-5C33F6E4D448.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).